Gene-level copy-number profile of tumor specimen TCGA-86-8674-01A from TCGA case TCGA-86-8674, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 50.6 years (18,479 days).
Specimen TCGA-86-8674-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.9c0df482-6323-4fb9-930f-e4a2343250f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-86-8674-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/674552aa-e630-40e8-b99a-09b344622642

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,752; copy number 3: 34; copy number 4: 48,411; copy number 6: 4,019; copy number 8: 2,604.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-86-8674-01A-21D-2389-01): tumor purity 0.58, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
